Somatic mutation profile of tumor specimen 0DV5SI from CCDI case PBCLRC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, malignant; Tissue or organ of origin: Ovary; Age at diagnosis: 12.2 years (4,447 days).
Specimen 0DV5SI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef095631-a8dd-4945-860c-3f58d35a2bd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0240d6f8-138a-475b-a710-26b062b36a01

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 43/248 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OR5D14 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 70/466 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV59457580; called by mutect2, varscan2
- SEC31A | c.3386G>A p.R1129H (on ENST00000355196 / NM_001318120.1; = p.R1090H on NM_016211.4) | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs761527824; called by muse, mutect2, varscan2
- UTP14A | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 17/511 reads (3%) | catalogued as COSV64087526; called by muse, mutect2
- ARHGAP23 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- INTS6 | c.649A>C p.N217H | Missense Mutation (SNP) | VAF 104/525 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NOL8 | c.3335G>T p.R1112I | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYA1 | c.1575T>C p.N525= | Silent (SNP) | VAF 32/556 reads (6%) | called by muse, mutect2
- PLIN4 | c.3159C>T p.L1053= (on ENST00000301286; = p.L1068= on NM_001367868.2) | Silent (SNP) | VAF 13/233 reads (6%) | called by muse, mutect2
- CADPS | c.3329+74G>T | Intron (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
